Somatic mutation profile of tumor specimen TCGA-36-2532-01A (aliquot TCGA-36-2532-01A-01D-1526-09) from TCGA case TCGA-36-2532, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.1 years (22,333 days).
Specimen TCGA-36-2532-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9909823e-d741-4985-933f-59879ab7c3bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2532-10A (Blood Derived Normal), aliquot TCGA-36-2532-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/019e64a2-24ca-43e9-92fa-b71a142262a2

The open-access MAF lists 47 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 76/96 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGO3 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 157/367 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as rs1342440409, COSV55793063; called by muse, mutect2, varscan2
- ALG1L | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 125/455 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as COSV61076757; called by muse, mutect2, varscan2
- APMAP | c.591G>T p.M197I | Missense Mutation (SNP) | VAF 185/431 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV54177183; called by muse, mutect2, varscan2
- ARHGEF17 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 108/211 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV55238583; called by muse, mutect2, varscan2
- ARMC3 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1389228963, COSV53057828; called by muse, mutect2, varscan2
- ATP11B | c.995G>C p.S332T | Missense Mutation (SNP) | VAF 99/206 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.115); catalogued as COSV60033655; called by muse, mutect2, varscan2
- CACNA1D | c.3068C>G p.T1023S (on ENST00000350061 / NM_001128840.3; = p.T1043S on NM_000720.4) | Missense Mutation (SNP) | VAF 222/554 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV55465939; called by muse, mutect2, varscan2
- DLX2 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414617008, COSV52233002; called by muse, mutect2, varscan2
- ENO3 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 100/142 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs143749502; called by muse, mutect2, varscan2
- EPHX2 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 272/694 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs574326427, COSV66845380; called by muse, mutect2, varscan2
- FOCAD | c.2719-1G>A p.X907_splice | Splice Site (SNP) | VAF 197/635 reads (31%) | catalogued as COSV58108082; called by muse, mutect2, varscan2
- GCC2 | c.3091G>C p.E1031Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1309185054, COSV59180292; called by muse, mutect2, varscan2
- H4C3 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as COSV100619460; called by muse, mutect2
- IPO9 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.142); catalogued as COSV55227048; called by muse, mutect2
- KIAA1958 | c.1511G>A p.S504N | Missense Mutation (SNP) | VAF 150/297 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV61728457; called by muse, mutect2, varscan2
- KLHL24 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV99664638; called by muse, mutect2
- MBL2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 203/256 reads (79%) | SIFT tolerated (0.1); PolyPhen benign (0.338); catalogued as rs776551094, COSV64759113; called by muse, mutect2, varscan2
- PCNA | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 5/149 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.123); catalogued as COSV99176937; called by muse, mutect2
- PIK3CD | c.2113A>G p.K705E | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV63132054; called by muse, mutect2, varscan2
- PPRC1 | c.1648G>C p.A550P | Missense Mutation (SNP) | VAF 90/120 reads (75%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV53388787; called by muse, mutect2, varscan2
- PRXL2A | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 223/1362 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as COSV64691267; called by muse, mutect2, varscan2
- PTGDS | c.114G>A p.K38= | Splice Region (SNP) | VAF 25/235 reads (11%) | catalogued as COSV56401580; called by muse, mutect2, varscan2
- RTL4 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 87/221 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as COSV61206563; called by muse, mutect2, varscan2
- RXFP3 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1157944873, COSV57504229, COSV57508376; called by muse, mutect2, varscan2
- SEMA4D | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 60/566 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as rs150298124, COSV59401265; called by muse, mutect2, varscan2
- SLC52A2 | c.692C>G p.S231* | Nonsense Mutation (SNP) | VAF 62/258 reads (24%) | catalogued as COSV57353680; called by muse, varscan2
- SPINT1 | c.1352G>A p.G451D (on ENST00000344051 / NM_181642.3; = p.G435D on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/332 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV59803525; called by muse, mutect2, varscan2
- STAB2 | c.3441G>T p.M1147I | Missense Mutation (SNP) | VAF 101/256 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as COSV66347691; called by muse, mutect2, varscan2
- SVIL | c.4861C>T p.Q1621* (on ENST00000355867 / NM_021738.3; = p.Q1195* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/734 reads (3%) | catalogued as rs1470420892, COSV100880768; called by muse, mutect2
- TUSC3 | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV65887215; called by muse, mutect2, varscan2
- ZNF165 | c.1253A>G p.H418R | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs547337001, COSV66103013; called by muse, mutect2, varscan2
- ZNF438 | c.2269T>C p.C757R | Missense Mutation (SNP) | VAF 250/379 reads (66%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59201101; called by muse, mutect2, varscan2
- ARFGAP2 | c.191+2del p.X64_splice | Splice Site (DEL) | VAF 89/355 reads (25%) | called by mutect2, pindel, varscan2
- NF1 | c.3045del p.C1016Vfs*3 | Frame Shift Del (DEL) | VAF 46/80 reads (58%) | called by mutect2, pindel, varscan2
- POGZ | c.2018_2022del p.F673* | Frame Shift Del (DEL) | VAF 136/334 reads (41%) | called by mutect2, pindel, varscan2
- ANAPC2 | c.732C>T p.S244= | Silent (SNP) | VAF 246/430 reads (57%) | catalogued as COSV58809231; called by muse, mutect2, varscan2
- DHX38 | c.1893G>A p.G631= | Silent (SNP) | VAF 194/243 reads (80%) | catalogued as COSV51701142; called by muse, mutect2, varscan2
- FXR1 | c.12G>A p.L4= | Silent (SNP) | VAF 29/984 reads (3%) | catalogued as COSV99976004; called by muse, mutect2
- LRFN2 | c.1917C>A p.P639= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as COSV57835052; called by muse, mutect2, varscan2
- MUC17 | c.12201T>G p.P4067= | Silent (SNP) | VAF 300/690 reads (43%) | catalogued as COSV60304356; called by muse, mutect2, varscan2
- PCDHB3 | c.2265G>A p.L755= | Silent (SNP) | VAF 111/365 reads (30%) | catalogued as COSV50636216; called by muse, mutect2, varscan2
- SDC3 | c.1218G>T p.L406= | Silent (SNP) | VAF 148/351 reads (42%) | catalogued as COSV59580903; called by muse, mutect2, varscan2
- SLC52A2 | c.198C>T p.T66= | Silent (SNP) | VAF 189/590 reads (32%) | catalogued as rs782249337, COSV57353655; called by muse, mutect2, varscan2
- SLC52A2 | c.903C>T p.S301= | Silent (SNP) | VAF 74/267 reads (28%) | catalogued as rs782631231, COSV57353692; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM60 | c.45C>T p.F15= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV51892467, COSV51899151; called by muse, mutect2, varscan2
- LINC01565 | n.984A>T | RNA (SNP) | VAF 65/179 reads (36%) | called by muse, mutect2, varscan2
